Gene-level copy-number profile of tumor specimen HCM-SANG-1337-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-1337-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS.
Specimen HCM-SANG-1337-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e9809117-d48b-464d-b5e3-eda8107d26ec.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1337-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/4f3627f6-a2e2-4bf9-95a7-433b6b0a29a5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 12,433; copy number 2: 44,095; copy number 3: 1,513; copy number 4: 203; copy number 5: 662.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–1): RPS10P2.
- chr20:14,933,843–15,280,873, 4 genes (within-gene range 0–1): AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 662 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:19,212,642–19,722,926, 1 gene, copy number 5 (within-gene range 3–5): SLC24A3.
- chr20:19,693,209–20,056,046, 6 genes, copy number 5 (within-gene range 3–5): AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1.
- chr20:34,833,575–50,585,879, 411 genes, copy number 5 (broad region; genes not listed).
- chr20:52,192,159–52,699,472, 6 genes, copy number 5 (within-gene range 4–5): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1.
- chr20:53,552,770–54,269,542, 12 genes, copy number 5: AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1.
- chr20:57,110,640–64,327,972, 226 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,524. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
